Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EH, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EH-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site Code: Liver C22.0

1/19/11 *ju*

Patient Key:
Surgical date:

REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 B1 C1 D1 D2 D3 D4 D5 D6 D7 D8
Right lobe liver (1035 grams, 22.7 x 13.8 x 10.6 cm), tissue from the left portal vein (thrombus, 1.8 x 1.5 x 0.4 cm), gallbladder (9.2 x 3.1 x 1.3 cm) and peri-choledochal lymph nodes (together measuring 4.1 x 2.0 x 1.3 cm).

DIAGNOSIS:

Liver, right lobe, resection: Grade 3 (of 4) hepatocellular carcinoma is identified forming a multinodular mass (15.3 x 13.2 x 7.6 cm) associated with vascular invasion. There are multiple (7) satellite nodules ranging in size from 0.3 cm to 2.7 cm in greatest dimension. Tumor extends to within 0.1 cm of the surgical resection margin. Tumor thrombus is also present within the vein but the vessel margin is negative. Embolic material and coils also identified. Assessment of nonneoplastic liver to be reported in an addendum. ✓

Soft tissue, left portal vein, excision: Positive for hepatocellular carcinoma.

Gallbladder, cholecystectomy: Without diagnostic abnormality. Negative for malignancy.

Lymph nodes, peri-choledochal, excision: Multiple (6) peri-choledochal lymph nodes are negative for tumor.

ADDENDUM:

Non-neoplastic liver shows inactive chronic hepatitis with bridging fibrosis (stage 3), consistent with the patient's known history of chronic hepatitis B.

[page 2 of 4]
Patient Key:
Surgical date:

REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 B1 C1 D1 D2 D3 D4 D5 D6 D7 D8
Right lobe liver (1035 grams, 22.7 x 13.8 x 10.6 cm), tissue from the left portal vein (thrombus, 1.8 x 1.5 x 0.4 cm), gallbladder (9.2 x 3.1 x 1.3 cm) and peri-choledochal lymph nodes (together measuring 4.1 x 2.0 x 1.3 cm).

DIAGNOSIS:

Liver, right lobe, resection: Grade 3 (of 4) hepatocellular carcinoma is identified forming a multinodular mass (15.3 x 13.2 x 7.6 cm) associated with vascular invasion. There are multiple (7) satellite nodules ranging in size from 0.3 cm to 2.7 cm in greatest dimension. Tumor extends to within 0.1 cm of the surgical resection margin. Tumor thrombus is also present within the vein but the vessel margin is negative. Embolic material and coils also identified. Assessment of nonneoplastic liver to be reported in an addendum.

Soft tissue, left portal vein, excision: Positive for hepatocellular carcinoma.

Gallbladder, cholecystectomy: Without diagnostic abnormality. Negative for malignancy.

Lymph nodes, peri-choledochal, excision: Multiple (6) peri-choledochal lymph nodes are negative for tumor.

ADDENDUM:

Non-neoplastic liver shows inactive chronic hepatitis with bridging fibrosis (stage 3), consistent with the patient's known history of chronic hepatitis B.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☒ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☐ Solitary (specify location): _____
☒ Multiple (specify location): HN, right lobe

Tumor Size

Greatest dimension: 16.5 cm

*Additional dimensions: 7.7 x 1.5 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC**Histologic Type**

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☐ GI: Well differentiated
☐ GII: Moderately differentiated
☒ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
- ☐ pT0: No evidence of primary tumor
- ☐ pT1: Solitary tumor with no vascular invasion
- ☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
- ☒ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
- ☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
- ☐ pN0: No regional lymph node metastasis
- ☐ pN1: Regional lymph node metastasis

Specify: Number examined:

Number involved:

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
- ☐ pM1: Distant metastasis

*Specify site(s), if known:

Margins (check all that apply)

Parenchymal Margin

- ☐ Cannot be assessed
- ☒ Uninvolved by invasive carcinoma
- Distance of invasive carcinoma from closest margin: 1.0 mm
- Specify margin:
- ☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
- ☐ Uninvolved by invasive carcinoma
- * ☐ Carcinoma in situ absent
- * ☐ Carcinoma in situ present
- ☐ Involved by invasive carcinoma

Other Margin

- Specify margin: vessel margin
- ☒ Cannot be assessed
- ☒ Uninvolved by invasive carcinoma
- ☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☒ Absent
- * ☒ Present
- * ☐ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
- * ☐ Hepatocellular dysplasia
- * ☐ Ductal dysplasia
- * ☒ Cirrhosis/fibrosis stage 3
- * ☐ Iron overload
- * ☒ Hepatitis (specify type): chronic hepatitis B
- * ☐ Other (specify):

Source: NCI Genomic Data Commons file c9709352-62e3-4141-869f-6ab9d2c4a7ae (TCGA-DD-A1EH.951E7AFB-F380-4FA8-B213-CB766A60FF5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).